MMRF case MMRF_2018 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/80cd5ce5-3b21-4dbc-bd99-b7a021818110

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.1 years (25,962 days); ISS stage: II; Days to last known disease status: 938 days (2.6 years); Days to last follow up: 938 days (2.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 29 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 126 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 80 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 126 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -11 (ECOG 0): M Protein 4.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 53 mg/dL; Immunoglobulin G 57 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 4.69 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.53 mmol/L; Albumin 40 g/L; Total Protein 10.3 g/dL; Glucose 5.67 mmol/L.
- Day 80 (ECOG 0): M Protein 1.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.575 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.9 mg/dL; Immunoglobulin G 17.6 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 7.6 g/dL; Glucose 7.59 mmol/L.
- Day 204 (ECOG 0): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.55 mg/dL; Immunoglobulin G 6.09 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.15 mmol/L; Albumin 31 g/L; Total Protein 5.3 g/dL; Glucose 5.12 mmol/L.
- Day 378 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.769 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 4.23 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 5.4 g/dL; Glucose 7.87 mmol/L.
- Day 455 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 4.32 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 11.4 ×10⁹/L; Absolute Neutrophil 10.4 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 5.5 g/dL; Glucose 6.27 mmol/L.
- Day 528: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 3.32 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 6.16 mmol/L.
- Day 616 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.453 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.586 mg/dL; Immunoglobulin G 3.67 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 11.8 ×10⁹/L; Absolute Neutrophil 11.1 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 5.4 g/dL; Glucose 5.72 mmol/L.
- Day 721 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.937 mg/dL; Immunoglobulin G 3.71 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 5 g/dL; Glucose 7.65 mmol/L.
- Day 811: M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.999 mg/dL; Immunoglobulin G 3.35 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 93 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 5.1 g/dL; Glucose 4.4 mmol/L.
- Day 881: M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.884 mg/dL; Immunoglobulin G 3.38 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 6.38 mmol/L.
- Day 938 (ECOG 0): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.694 mg/dL; Immunoglobulin G 3.35 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 5.5 g/dL; Glucose 8.58 mmol/L.

Other clinical attributes
- Day -11: Weight: 68 kg; Height: 171 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2018_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -11 days.
- Sample MMRF_2018_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -11 days.
